Surgical pathology report (de-identified scan), TCGA case TCGA-LN-A7HZ, project TCGA-ESCA (Esophageal Carcinoma), tissue source site ILSBIO, specimen TCGA-LN-A7HZ-01A (Primary Tumor).

[page 1 of 5]
IRB APPROVED

Clinical Case Report

(For Collection of Cancerous Tissue)

ICD-O-3

Carcinoma, squamous
cell NOS 8070/3
Site Esophagus, upper
third C15.3
JN 10/10/13

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight	☐ Single ☒ Married ☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
☒ Male ☐ Female				

HISTORY OF PRESENT ILLNESS
Chief Complaints: Trouble Swallowing.
Symptoms: Tired of eating, weakness.
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☒ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☐ Pre-menopausal		
☐ Peri-Menopausal	Date of Last Menses	# of Live Births
☐ Post-menopausal		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☒ YES ☐ NO		1 p/day	25 (yrs)	Still smoke (yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO		1 drink/day	20 (yrs)	3 months ago (yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy	A tumour was found in the oesophagus	
MRI		
Biopsy		

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	Date of Diagnosis
T 2 N 0 M 0 Stage: II A	

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
Resection of the upper part of oesophagus			
Primary Tumor			
Organ	Detailed Location	Size	
oesophageal tumor	upper third	1 x 2 x 1 cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T 2 N 0 M 0 Stage: II A			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: _____

_____ Date: _____ Time: _____

Preserved by: _____

_____ Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	3	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
10 min		11 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
esophageal Tumor	4 x 2 x 1 cm	upper third	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 2 N 0 M 0		Stage: IIA	
Notes:			

[page 5 of 5]
IRB APPROVED

Consolidated Pathology Diagnosis

Histological Patterns											
Cell Distribution			Structural Pattern								
	+	-		+	-						
Diffuse		☒	Streaming								
Mosaic	☒		Storiform								
Necrosis		☒	Fibrosis								
Lymphocytic Infiltration	☒		Palisading								
Vascular Invasion		☒	Cystic Degeneration								
Clusterized		☒	Bleeding								
Alveolar Formation		☒	Myxoid Change								
Indian File		☒	Psammoma/Calcification								

Cellular Differentiation											
Squamous			Adenomatous			Sarcomatous			Lymphomatous		
	+	-		+	-		+	-		+	-
Squamoid Cell	☒		Glandular cell			Round Cell			Large Cell		
Spindle Cell	☒		Cell Stratification			Fibroblast			Small Cell		
Keratin	☒		Secretion			Osteoblast			RS Cell/RS Like		
Desmosome	☒		Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl		☒	Gland formation			Myoblast			Plasma Cell		

Cellular Differentiation: ☐ Well ☒ Moderate ☐ Poor

Nuclear Atypia:				
	0	I	II	III
Aniso Nucleosis			☒	
Hyperchromatism			☒	
Nucleolar Prominent			☒	
Multinucleated Giant Cell			☒	
Mitotic Activity			☒	

Nuclear Grade: 1

D702 b2703 b3 702. b4 702

Final Pathology Report

Histological Diagnosis: Squamous Cell Carcinoma Grade: 2

Comments:

Director, Research Pathology

Date

INTEGRATED REPORT OF FINDINGS BY COLLABORATORS AND

PATHOLOGISTS -

Source: NCI Genomic Data Commons file be2e3fb2-f9df-460c-a8cc-fbf40ae880c7 (TCGA-LN-A7HZ.09349C95-78DD-4218-B84F-8D14C9B32A3A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).